Somatic mutation profile of tumor specimen MP2PRT-PASZKY-TMP1-A (aliquot MP2PRT-PASZKY-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PASZKY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.9 years (4,725 days).
Specimen MP2PRT-PASZKY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab512257-9c41-48aa-9e03-9b73a125e6dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASZKY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASZKY-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/216f2ad9-a8c3-4c64-8a35-29ba632d9fd8

The open-access MAF lists 37 somatic variants for this specimen: 24 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 12, Frame Shift Ins 2, Nonsense Mutation 2, Intron 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 297/357 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APOH | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 119/456 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.125); catalogued as rs763687723; called by muse, mutect2, varscan2
- CA5A | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 183/382 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as rs369651699, COSV59240712; called by muse, mutect2, varscan2
- CBY2 | c.647C>T p.S216L | Missense Mutation (SNP) | VAF 20/454 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.463); catalogued as COSV60118520; called by muse, mutect2
- CLCN7 | c.1997A>T p.H666L | Missense Mutation (SNP) | VAF 72/228 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV51969717; called by muse, mutect2, varscan2
- COL6A1 | c.2911G>A p.V971M | Missense Mutation (SNP) | VAF 268/1097 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.196); catalogued as rs769795690; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- CROCC2 | c.2467C>T p.R823W | Missense Mutation (SNP) | VAF 22/397 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.116); catalogued as rs1441839085; called by muse, mutect2
- DLGAP1 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 225/502 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1344032507, COSV59785214; called by muse, mutect2, varscan2
- FIGN | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 27/413 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as rs770886664; called by muse, mutect2
- GPR180 | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 18/370 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs1324564123; called by muse, mutect2
- HECW1 | c.1580C>T p.S527L | Missense Mutation (SNP) | VAF 205/638 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV67840837; called by muse, mutect2, varscan2
- MROH9 | c.1193C>T p.A398V | Missense Mutation (SNP) | VAF 89/137 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as rs750550050, COSV63010911; called by muse, mutect2, varscan2
- STAG2 | c.3673-1G>A p.X1225_splice | Splice Site (SNP) | VAF 15/141 reads (11%) | catalogued as COSV54362246; called by muse, mutect2, varscan2
- TH | c.1519C>T p.R507W (on ENST00000381178 / NM_199292.3; = p.R476W on NM_000360.4) | Missense Mutation (SNP) | VAF 198/442 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs201616746; called by muse, varscan2
- TMEM63B | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 206/675 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.025); catalogued as rs750117918; called by muse, mutect2, varscan2
- USP44 | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 153/336 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs755556772, COSV51562769; called by muse, mutect2, varscan2
- CACNA1B | c.3225C>A p.N1075K | Missense Mutation (SNP) | VAF 24/446 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.01); called by muse, mutect2
- KIF9 | c.711dup p.T238Hfs*5 | Frame Shift Ins (INS) | VAF 79/316 reads (25%) | called by mutect2, pindel, varscan2
- MANEA | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 27/172 reads (16%) | called by muse, mutect2, varscan2
- MXRA5 | c.6841G>T p.D2281Y | Missense Mutation (SNP) | VAF 38/1170 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PTPRB | c.2612_2613insGGTTTTT p.E872Vfs*23 | Frame Shift Ins (INS) | VAF 125/339 reads (37%) | called by mutect2, pindel*, varscan2*
- RC3H2 | c.3394del p.T1132Qfs*5 | Frame Shift Del (DEL) | VAF 61/255 reads (24%) | called by mutect2, pindel, varscan2
- ROBO2 | c.667G>T p.E223* | Nonsense Mutation (SNP) | VAF 80/169 reads (47%) | called by muse, mutect2, varscan2
- ZNF407 | c.625A>G p.M209V | Missense Mutation (SNP) | VAF 150/327 reads (46%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- BEX1 | c.19C>A p.R7= | Silent (SNP) | VAF 112/538 reads (21%) | called by muse, mutect2, varscan2
- CDH20 | c.2109C>T p.P703= | Silent (SNP) | VAF 155/483 reads (32%) | catalogued as rs139351388, COSV53004309, COSV53004918; called by muse, mutect2, varscan2
- CLCN7 | c.1998T>C p.H666= | Silent (SNP) | VAF 71/226 reads (31%) | called by muse, mutect2, varscan2
- FAT4 | c.12186C>T p.H4062= | Silent (SNP) | VAF 16/342 reads (5%) | called by muse, mutect2
- GLIS3 | c.144G>A p.S48= | Silent (SNP) | VAF 85/237 reads (36%) | catalogued as rs148306701; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IQSEC3 | c.1245C>T p.D415= (on ENST00000538872 / NM_001170738.2; = p.D112= on NM_015232.1) | Silent (SNP) | VAF 25/550 reads (5%) | catalogued as rs991127989; called by muse, mutect2
- MROH9 | c.1768C>T p.L590= | Silent (SNP) | VAF 97/207 reads (47%) | catalogued as rs1179337029; called by muse, mutect2, varscan2
- RNF31 | c.2700C>A p.G900= | Silent (SNP) | VAF 126/557 reads (23%) | called by muse, mutect2, varscan2
- RTL3 | c.564C>T p.P188= | Silent (SNP) | VAF 120/907 reads (13%) | catalogued as rs1455892107; called by muse, mutect2, varscan2
- TENM4 | c.75G>A p.S25= | Silent (SNP) | VAF 247/523 reads (47%) | called by muse, mutect2, varscan2
- TEX13D | c.132C>T p.N44= | Silent (SNP) | VAF 134/649 reads (21%) | called by muse, mutect2, varscan2
- VRTN | c.882C>T p.S294= | Silent (SNP) | VAF 157/950 reads (17%) | called by muse, mutect2, varscan2
- GRM8 | c.2677+23G>A | Intron (SNP) | VAF 107/228 reads (47%) | catalogued as rs146609882, COSV100286982, COSV58873365; called by muse, mutect2, varscan2
